Somatic mutation profile of tumor specimen MP2PRT-PAVMSP-TMP1-A (aliquot MP2PRT-PAVMSP-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVMSP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,051 days).
Specimen MP2PRT-PAVMSP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f81d572-ee79-4d4e-90b3-dceae5eba0eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMSP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMSP-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/752f36d8-d9f5-46c3-9a7c-a278c6e33c6f

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QTNF8 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 198/463 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs778037932; called by muse, mutect2, varscan2
- CPB1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 166/475 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142211299; called by muse, mutect2, varscan2
- FOXG1 | c.1391C>T p.T464M | Missense Mutation (SNP) | VAF 157/397 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs1431069138, COSV57394904; called by muse, mutect2, varscan2
- KRT9 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 182/484 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.243); catalogued as rs867564871; called by muse, varscan2
- NPHS1 | c.2545G>A p.V849M | Missense Mutation (SNP) | VAF 158/444 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360430163; called by muse, mutect2, varscan2
- TNXB | c.12221C>T p.S4074L (on ENST00000647633; = p.S3827L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 227/611 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1008389232, COSV64477509; called by muse, mutect2, varscan2
- TRIM77 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 157/399 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs1249234025; called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714673 CACACTGTGTCTCTCGCACAGTA>TTT | Missense Mutation (DEL) | VAF 38/58 reads (66%) | called by pindel, varscan2*
- NAF1 | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 190/457 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PCDH18 | c.567G>T p.R189S | Missense Mutation (SNP) | VAF 132/303 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAE1 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 232/555 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SETD1B | c.5289C>A p.Y1763* | Nonsense Mutation (SNP) | VAF 213/490 reads (43%) | called by muse, mutect2, varscan2
- DST | c.4297-3577C>A | Intron (SNP) | VAF 118/354 reads (33%) | called by muse, mutect2
- IGHV1-58 | chr14:106627248 ins AGGGTA | 5'Flank (INS) | VAF 67/105 reads (64%) | called by mutect2, pindel, varscan2
